Somatic mutation profile of tumor specimen TCGA-A2-A0T5-01A (aliquot TCGA-A2-A0T5-01A-21D-A099-09) from TCGA case TCGA-A2-A0T5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 39.7 years (14,503 days).
Specimen TCGA-A2-A0T5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6b6dcef-7c2d-412c-a1c3-82e53e650826.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0T5-10A (Blood Derived Normal), aliquot TCGA-A2-A0T5-10A-01D-A099-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c7905e2-6817-424c-ac08-844be9a68686

The open-access MAF lists 16 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Ins 2, Frame Shift Del 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMPD1 | c.730G>A p.G244R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs120074122, CM920622, COSV54966614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.1118C>T p.P373L | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV56643964; called by muse, mutect2, varscan2
- AMOTL1 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54416164; called by muse, mutect2, varscan2
- ASPHD2 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.173); catalogued as COSV53219268; called by muse, mutect2, varscan2
- CEMIP | c.803del p.P268Lfs*5 | Frame Shift Del (DEL) | VAF 50/136 reads (37%) | catalogued as rs779771025; called by mutect2, pindel, varscan2
- EP300 | c.5528A>C p.Q1843P | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54333876; called by muse, mutect2, varscan2
- GRIN2C | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200788897; called by muse, mutect2, varscan2
- MEGF11 | c.2685G>A p.M895I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV56551912; called by muse, mutect2, varscan2
- PKM | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as rs747511396, COSV58788988; called by muse, mutect2, varscan2
- RARS1 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs752688554, COSV51563872; called by muse, mutect2, varscan2
- SPSB2 | c.491C>G p.P164R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51290201; called by muse, mutect2, varscan2
- TRIM38 | c.1093A>T p.M365L | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100837553; called by muse, varscan2
- CBFB | c.255_264del p.Y85* | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- GATA3 | c.1035_1036insTTAC p.K346Lfs*7 | Frame Shift Ins (INS) | VAF 32/113 reads (28%) | called by mutect2, pindel, varscan2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 48/172 reads (28%) | called by mutect2, pindel, varscan2
- CACNA1H | c.3114C>T p.F1038= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs374946880; ClinVar: likely benign; called by muse, mutect2, varscan2
